Somatic mutation profile of tumor specimen 0DT3UG from CCDI case PBCICR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.6 years (5,696 days).
Specimen 0DT3UG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9c5bced-cd6a-4fb6-aab3-6d77fa90ae51.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT3UP (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ff928db9-809d-4267-b6d4-f99c41f1dcd8

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 3, Intron 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCAM | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 144/476 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV99539076; called by muse, mutect2, varscan2
- CXorf56 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 110/878 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as rs774807972; called by muse, mutect2, varscan2
- EBF1 | c.824C>T p.T275M | Missense Mutation (SNP) | VAF 97/914 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs988910682, COSV58176135; called by muse, mutect2, varscan2
- TAF15 | c.1525G>A p.G509R (on ENST00000605844 / NM_139215.3; = p.G506R on NM_003487.4) | Missense Mutation (SNP) | VAF 235/806 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.013); catalogued as rs751345945; called by muse, mutect2, varscan2
- TTN | c.34909G>A p.V11637I (on ENST00000591111; = p.V10710I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 293/999 reads (29%) | PolyPhen benign (0); catalogued as rs374394719; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- HYAL4 | c.385del p.I129Lfs*16 | Frame Shift Del (DEL) | VAF 132/892 reads (15%) | called by mutect2, varscan2
- RP9 | c.533C>G p.S178C | Missense Mutation (SNP) | VAF 243/1546 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RUFY4 | c.1611C>A p.C537* | Nonsense Mutation (SNP) | VAF 44/392 reads (11%) | called by muse, mutect2, varscan2
- STEAP1B | c.84G>C p.L28F | Missense Mutation (SNP) | VAF 87/406 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- TRPC4AP | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 42/584 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.142); called by muse, mutect2
- WDR7 | c.3617G>C p.G1206A | Missense Mutation (SNP) | VAF 38/926 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- GNB2 | c.78G>C p.G26= | Silent (SNP) | VAF 178/940 reads (19%) | catalogued as COSV51947778; called by mutect2, varscan2
- LGI2 | c.963T>G p.S321= | Silent (SNP) | VAF 59/532 reads (11%) | called by muse, mutect2, varscan2
- NEGR1 | c.36C>T p.C12= | Silent (SNP) | VAF 38/418 reads (9%) | called by muse, mutect2
- ARHGAP6 | c.2177-55T>A | Intron (SNP) | VAF 60/200 reads (30%) | called by muse, mutect2, varscan2
- MUC3A | c.9612-25G>A | Intron (SNP) | VAF 55/351 reads (16%) | called by mutect2, varscan2
